Somatic mutation profile of tumor specimen SM-JU33O (aliquot 7316UP-743) from CPTAC case C224967, project CPTAC-3 (Complex Epithelial Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma.
Specimen SM-JU33O: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e69e6b90-5a54-4ec3-be0c-20a94fe0ea1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105291 (Blood Derived Normal), aliquot 7316UP-743-1105291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08d5aaed-a37d-4ab9-b866-e48e69a1b5da

The open-access MAF lists 226 somatic variants for this specimen: 174 protein-altering or splice-affecting, 37 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 37, Nonsense Mutation 10, Intron 5, Frame Shift Ins 5, Frame Shift Del 5, Splice Site 3, RNA 3, 3'UTR 3, Splice Region 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 86/523 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 421/460 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs779191648; called by muse, mutect2, varscan2
- AC100868.1 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51838929; called by muse, mutect2
- AC134980.2 | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 117/136 reads (86%) | catalogued as COSV60906617; called by muse, mutect2, varscan2
- AK5 | c.114G>T p.L38F (on ENST00000354567 / NM_174858.3; = p.L12F on NM_012093.4) | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100481326; called by muse, mutect2, varscan2
- APBA1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV55238263; called by muse, mutect2, varscan2
- ASB4 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 63/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750596265; called by muse, mutect2, varscan2
- ATP13A2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 188/209 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764344537; called by muse, mutect2, varscan2
- C4orf54 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 151/173 reads (87%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV72767064; called by muse, mutect2, varscan2
- CHRNB4 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 263/420 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55715447; called by muse, mutect2, varscan2
- CLCN2 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 1403/1933 reads (73%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771299323, COSV55601161; called by muse, mutect2, varscan2
- CLEC4E | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 67/156 reads (43%) | catalogued as COSV55226819; called by muse, mutect2, varscan2
- CLIP1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 189/375 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1426526590; called by muse, mutect2, varscan2
- CLUH | c.739C>T p.R247W (on ENST00000435359; = p.R285W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1196033304; called by muse, mutect2
- CTNNA2 | c.1507A>G p.I503V | Missense Mutation (SNP) | VAF 128/246 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as rs1377768390; called by muse, mutect2, varscan2
- CTNND1 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV62383870; called by muse, mutect2, varscan2
- DPP10 | c.125T>G p.I42S | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100068362; called by muse, mutect2, varscan2
- FCER2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs755933015; called by muse, mutect2, varscan2
- GLB1L | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs747707530; called by muse, mutect2, varscan2
- GSG1L2 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 134/655 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV52327476; called by muse, mutect2
- GTF3C1 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 237/1164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55183619; called by muse, mutect2, varscan2
- HMBS | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0911046; called by muse, mutect2, varscan2
- IGLV1-36 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs532396053; called by muse, mutect2, varscan2
- IL16 | c.3276dup p.L1093Tfs*10 (on ENST00000302987 / NM_172217.5; = p.L392Tfs*10 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/168 reads (20%) | catalogued as rs777448128; called by mutect2, varscan2
- KCNJ12 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 191/781 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs755030830; called by muse, mutect2, varscan2
- KEAP1 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50565587; called by muse, mutect2, varscan2
- KRT72 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 502/1054 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs779414132; called by muse, mutect2, varscan2
- LRP1B | c.9524G>T p.R3175I | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV101257726; called by muse, mutect2, varscan2
- LRRTM4 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 109/224 reads (49%) | catalogued as rs1484615851, COSV69139560, COSV69139830; called by muse, mutect2, varscan2
- LUM | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 82/217 reads (38%) | catalogued as COSV57127483, COSV57127798; called by muse, mutect2, varscan2
- MRC1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 143/710 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1445835500; called by muse, mutect2, varscan2
- MTUS2 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 115/135 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1432651915; called by muse, mutect2, varscan2
- NADSYN1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as rs142449261; called by muse, mutect2, varscan2
- NAV3 | c.6749T>C p.V2250A (on ENST00000397909 / NM_001024383.2; = p.V2228A on NM_014903.6) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV57076289; called by muse, mutect2, varscan2
- NR6A1 | c.1261A>G p.I421V (on ENST00000487099 / NM_033334.4; = p.I416V on NM_001489.5) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775195028; called by muse, mutect2, varscan2
- NT5C1B | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV58398234; called by muse, mutect2, varscan2
- OR2M2 | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 111/295 reads (38%) | catalogued as COSV62897809, COSV62898568; called by muse, mutect2, varscan2
- OR2M2 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 115/296 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100677226; called by muse, mutect2, varscan2
- OR2M2 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100677182; called by muse, mutect2, varscan2
- OR2T34 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1479320964; called by muse, mutect2, varscan2
- OR52A1 | c.787_789del p.F263del | In Frame Del (DEL) | VAF 20/124 reads (16%) | catalogued as rs766997566; called by pindel, varscan2
- PEX5L | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV55850021; called by muse, mutect2
- PLD2 | c.903G>T p.W301C | Missense Mutation (SNP) | VAF 128/259 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs748710430; called by muse, varscan2
- POLR3D | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.75); catalogued as rs554801170; called by muse, mutect2
- PRPSAP1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771369497; called by muse, mutect2, varscan2
- PTK2 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150568425, COSV61787289; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 149/338 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs751434439, COSV54590426; called by muse, mutect2, varscan2
- RP1 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV55125063; called by muse, mutect2, varscan2
- RUNX1T1 | c.1304G>A p.R435K (on ENST00000265814 / NM_001198628.1; = p.R408K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV56166353; called by muse, mutect2, varscan2
- RYR1 | c.8477C>A p.A2826D | Missense Mutation (SNP) | VAF 96/929 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100615723; called by muse, mutect2, varscan2
- SF3B1 | c.2255A>T p.Y752F | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV59212391; called by muse, varscan2
- SLC44A1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs761961178, COSV100570645; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1961C>T p.A654V (on ENST00000540229 / NM_001371097.1; = p.A593V on NM_001009562.4) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV67445651; called by muse, varscan2
- SP8 | c.1124C>T p.A375V (on ENST00000361443 / NM_198956.4; = p.A393V on NM_182700.6) | Missense Mutation (SNP) | VAF 176/1316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815323; called by muse, mutect2, varscan2
- SPEF2 | c.5131C>A p.P1711T | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.599); catalogued as COSV57433439; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 73/286 reads (26%) | PolyPhen benign (0.033); catalogued as COSV52536424; called by muse, mutect2, varscan2
- STAT4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 213/343 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs758217844; called by muse, mutect2, varscan2
- TAS2R8 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs780966630; called by muse, mutect2, varscan2
- TFEB | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs757546185, COSV57824976; called by muse, mutect2, varscan2
- TMEM132D | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 222/478 reads (46%) | catalogued as COSV70605643; called by muse, mutect2, varscan2
- TMEM52B | c.403C>G p.L135V (on ENST00000381923 / NM_001079815.1; = p.L115V on NM_153022.4) | Missense Mutation (SNP) | VAF 265/641 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.708); catalogued as COSV100046359; called by muse, mutect2, varscan2
- UNC13C | c.4069G>C p.A1357P | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1204811388; called by muse, mutect2, varscan2
- YJU2 | c.585C>T p.T195= | Splice Region (SNP) | VAF 101/210 reads (48%) | catalogued as rs527648441, COSV53608057; called by muse, mutect2, varscan2
- ZBTB11 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 68/142 reads (48%) | catalogued as COSV100465609; called by muse, mutect2, varscan2
- ZNF536 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 82/425 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200453890, COSV62825016; called by muse, mutect2, varscan2
- ZNF746 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs775508372, COSV100502494; called by muse, mutect2, varscan2
- ZNF99 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs530998365; called by muse, varscan2
- ADAM18 | c.2099T>A p.F700Y | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADGRB1 | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 333/686 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCYL2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 326/911 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ALDH3A1 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMOTL2 | c.619del p.R207Efs*12 | Frame Shift Del (DEL) | VAF 34/64 reads (53%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.1258A>G p.R420G | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APOB | c.13450A>T p.T4484S | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- APOB | c.10706dup p.N3569Kfs*44 | Frame Shift Ins (INS) | VAF 110/315 reads (35%) | called by mutect2, pindel, varscan2
- APOB | c.3466G>A p.A1156T | Missense Mutation (SNP) | VAF 188/388 reads (48%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ASNS | c.756G>C p.R252S | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BCHE | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BCL11B | c.1744G>T p.G582C (on ENST00000357195 / NM_001282237.2; = p.G511C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/710 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CCDC17 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CENPS | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFH | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CFHR5 | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CUX1 | c.4417G>A p.D1473N | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- CYB561A3 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CYSLTR2 | c.846A>T p.R282S | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- DGKK | c.757-1G>T p.X253_splice | Splice Site (SNP) | VAF 30/39 reads (77%) | called by muse, mutect2, varscan2
- DLGAP4 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 155/416 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EDIL3 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML4 | c.2534dup p.N845Kfs*2 | Frame Shift Ins (INS) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.2855dup p.N953Kfs*11 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- EYS | c.5287G>T p.E1763* | Nonsense Mutation (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- FAM135B | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAT1 | c.6916_6928del p.R2306Lfs*26 | Frame Shift Del (DEL) | VAF 72/90 reads (80%) | called by mutect2, pindel, varscan2
- FSIP2 | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GCKR | c.1144-7G>T | Splice Region (SNP) | VAF 130/313 reads (42%) | called by muse, mutect2, varscan2
- GJD4 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 185/266 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GREB1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM6 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 241/263 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC2 | c.3004G>T p.G1002C | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ISM2 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ITGAM | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KAT14 | c.2185G>A p.G729S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, varscan2
- KAT6A | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIAA1217 | c.3569C>G p.S1190C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2D | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- KMT2D | c.1106del p.C369Lfs*33 | Frame Shift Del (DEL) | VAF 74/174 reads (43%) | called by mutect2, pindel*, varscan2*
- KRBOX4 | c.216del p.T73Pfs*21 (on ENST00000344302 / NM_001129898.2; = p.T73Pfs*16 on NM_017776.2) | Frame Shift Del (DEL) | VAF 76/120 reads (63%) | called by mutect2, pindel, varscan2
- KRT222 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT35 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- L3MBTL3 | c.1703A>T p.H568L | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMP3 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 127/793 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LDAH | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAGEC1 | c.2003A>T p.E668V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MAGEC2 | c.20T>G p.V7G | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MDGA2 | c.949G>T p.V317L (on ENST00000399232 / NM_001113498.2; = p.V19L on NM_182830.4) | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- METTL11B | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 167/357 reads (47%) | called by mutect2, varscan2
- MPZL2 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MS4A8 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MUC17 | c.5195C>A p.T1732K | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC17 | c.10090C>T p.P3364S | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MYO7B | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDC1 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- NFIC | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 275/732 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOM1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NRBP1 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 220/493 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NXF1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OPN1SW | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 238/769 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M3 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51B4 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- OR52E6 | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCDH11X | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PCDHA10 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 364/411 reads (89%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PCNT | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 206/1131 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, varscan2
- PDE10A | c.990del p.E331Rfs*2 | Frame Shift Del (DEL) | VAF 52/137 reads (38%) | called by mutect2, pindel, varscan2
- PDE4B | c.2125T>C p.C709R | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PDGFRA | c.367+1G>A p.X123_splice | Splice Site (SNP) | VAF 126/142 reads (89%) | called by muse, mutect2, varscan2
- PHACTR2 | c.1199G>T p.C400F | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLD2 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 124/254 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, varscan2
- PSG9 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 153/171 reads (89%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTK7 | c.3155C>G p.P1052R | Missense Mutation (SNP) | VAF 86/326 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRO | c.160T>A p.S54T | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RANBP2 | c.2560G>C p.G854R | Missense Mutation (SNP) | VAF 151/489 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- REV3L | c.9090A>T p.K3030N | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- RIOX2 | c.950A>G p.D317G (on ENST00000333396 / NM_001042533.2; = p.D316G on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 328/592 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RIT2 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTBDN | c.170-2A>G p.X57_splice (on ENST00000393233 / NM_001270444.1; = p.X89_splice on NM_031429.2) | Splice Site (SNP) | VAF 115/259 reads (44%) | called by muse, mutect2, varscan2
- RXFP2 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN9A | c.2057G>A p.R686K (on ENST00000303354; = p.R675K on NM_002977.3) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SERPING1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 155/436 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SF3B1 | c.2254T>A p.Y752N | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, varscan2
- SLC15A2 | c.1306A>C p.N436H | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC15A4 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC22A6 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 161/324 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC32A1 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 225/455 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SOX30 | c.2125A>C p.N709H | Missense Mutation (SNP) | VAF 124/144 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPEG | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.027); called by muse, mutect2
- SPHKAP | c.4136G>A p.C1379Y | Missense Mutation (SNP) | VAF 87/105 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ST18 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SYT10 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THAP5 | c.880G>C p.E294Q (on ENST00000415914 / NM_001130475.3; = p.E252Q on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/298 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TJP1 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TMEM115 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- TNR | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 118/309 reads (38%) | called by muse, mutect2, varscan2
- TTLL11 | c.1876T>A p.F626I | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3564C>A p.D1188E | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR97 | c.3345G>T p.W1115C | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- XIRP2 | c.2362T>A p.S788T (on ENST00000628543; = p.S963T on NM_152381.6) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF407 | c.3915T>A p.N1305K | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF568 | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF616 | c.1903T>G p.C635G | Missense Mutation (SNP) | VAF 131/146 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF676 | c.1019C>G p.P340R (on ENST00000650058; = p.P308R on NM_001001411.3) | Missense Mutation (SNP) | VAF 263/852 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZXDB | c.922dup p.L308Pfs*52 | Frame Shift Ins (INS) | VAF 93/152 reads (61%) | called by mutect2, pindel, varscan2
- ACADS | c.63C>T p.A21= | Silent (SNP) | VAF 226/508 reads (44%) | called by muse, mutect2, varscan2
- ANK3 | c.7980C>G p.P2660= | Silent (SNP) | VAF 158/236 reads (67%) | catalogued as rs1564795708, COSV55050187; called by muse, mutect2, varscan2
- ATAD3A | c.729G>A p.A243= | Silent (SNP) | VAF 312/366 reads (85%) | catalogued as rs549678655, COSV59233195; called by muse, mutect2, varscan2
- ATP5F1B | c.1344G>A p.E448= | Silent (SNP) | VAF 168/418 reads (40%) | catalogued as rs888471798, COSV51634247; called by muse, mutect2, varscan2
- BCHE | c.915A>C p.A305= | Silent (SNP) | VAF 77/301 reads (26%) | catalogued as COSV100012804; called by muse, mutect2, varscan2
- C15orf39 | c.2919G>T p.P973= | Silent (SNP) | VAF 92/320 reads (29%) | called by muse, mutect2, varscan2
- C1orf141 | c.255G>A p.E85= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- CENPB | c.312G>A p.A104= | Silent (SNP) | VAF 260/433 reads (60%) | called by muse, mutect2, varscan2
- CHRNA10 | c.711C>T p.A237= | Silent (SNP) | VAF 20/358 reads (6%) | catalogued as rs760737901, COSV51705025; called by muse, mutect2
- CSMD1 | c.3009G>C p.S1003= (on ENST00000520002; = p.S1002= on NM_033225.6) | Silent (SNP) | VAF 138/927 reads (15%) | called by muse, varscan2
- EVL | c.1146G>A p.R382= (on ENST00000402714 / NM_001330221.2; = p.R384= on NM_016337.3) | Silent (SNP) | VAF 90/130 reads (69%) | called by muse, mutect2, varscan2
- FAM160A1 | c.663C>T p.F221= | Silent (SNP) | VAF 82/178 reads (46%) | called by muse, mutect2, varscan2
- FFAR3 | c.330C>T p.S110= | Silent (SNP) | VAF 232/1810 reads (13%) | called by muse, mutect2, varscan2
- HEG1 | c.1026G>T p.T342= | Silent (SNP) | VAF 173/300 reads (58%) | called by muse, mutect2, varscan2
- HEPACAM | c.612C>T p.I204= | Silent (SNP) | VAF 64/261 reads (25%) | called by muse, mutect2, varscan2
- INSYN2B | c.255G>A p.R85= | Silent (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- LILRB5 | c.723C>T p.T241= | Silent (SNP) | VAF 119/243 reads (49%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1545T>C p.C515= (on ENST00000374979 / NM_001308027.2; = p.C463= on NM_024631.4) | Silent (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2799A>T p.P933= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- NRK | c.3402A>T p.I1134= | Silent (SNP) | VAF 56/58 reads (97%) | called by muse, mutect2, varscan2
- OR5H15 | c.795G>T p.P265= | Silent (SNP) | VAF 150/594 reads (25%) | catalogued as rs371915983; called by muse, mutect2, varscan2
- OSTM1 | c.93C>G p.G31= | Silent (SNP) | VAF 140/384 reads (36%) | called by muse, mutect2, varscan2
- PDPR | c.1509G>A p.K503= | Silent (SNP) | VAF 87/238 reads (37%) | called by muse, mutect2, varscan2
- PLEKHO2 | c.1161C>A p.R387= | Silent (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1536C>T p.G512= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as rs1288537855, COSV101234474; called by muse, mutect2
- SCN8A | c.1494G>A p.R498= | Silent (SNP) | VAF 82/207 reads (40%) | called by muse, mutect2, varscan2
- SELENOK | c.138G>A p.V46= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100212599; called by muse, mutect2, varscan2
- SF3B1 | c.2253G>T p.G751= | Silent (SNP) | VAF 33/311 reads (11%) | called by muse, varscan2
- SMYD1 | c.357C>T p.T119= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as rs779230496; called by mutect2, varscan2
- SOX15 | c.399C>A p.R133= | Silent (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- TLK2 | c.1902A>G p.T634= (on ENST00000326270 / NM_001284333.2; = p.T612= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs767032124; called by muse, mutect2, varscan2
- TMEM31 | c.411G>A p.K137= | Silent (SNP) | VAF 79/224 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.23655G>A p.V7885= (on ENST00000591111; = p.V6958= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/282 reads (25%) | catalogued as COSV60078851; called by muse, mutect2, varscan2
- WDR19 | c.2505C>G p.L835= | Silent (SNP) | VAF 62/73 reads (85%) | catalogued as COSV56464188; called by muse, mutect2, varscan2
- ZBTB11 | c.417G>A p.L139= | Silent (SNP) | VAF 66/142 reads (46%) | called by muse, mutect2, varscan2
- ZNF506 | c.873C>A p.G291= | Silent (SNP) | VAF 96/380 reads (25%) | called by muse, mutect2, varscan2
- ZNF768 | c.1062C>T p.F354= | Silent (SNP) | VAF 281/736 reads (38%) | catalogued as rs1459483118, COSV63323499; called by muse, mutect2, varscan2
- CABIN1 | c.4747-8424C>G | Intron (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- HERC2P3 | n.501C>A | RNA (SNP) | VAF 88/482 reads (18%) | called by muse, mutect2
- IGFN1 | c.1242-3554G>T | Intron (SNP) | VAF 149/845 reads (18%) | called by muse, varscan2
- KLRA1P | n.149C>T | RNA (SNP) | VAF 42/237 reads (18%) | catalogued as rs267603281; called by muse, mutect2, varscan2
- LMO3 | chr12:16605784 C>A | 5'Flank (SNP) | VAF 122/319 reads (38%) | called by muse, mutect2, varscan2
- NOL8 | c.282-797G>A | Intron (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157655 G>T | 5'Flank (SNP) | VAF 87/180 reads (48%) | catalogued as rs371282250; called by muse, mutect2, varscan2
- REXO4 | c.572+300G>A | Intron (SNP) | VAF 20/79 reads (25%) | catalogued as rs1274236594; called by muse, mutect2
- SERPINA13P | n.742C>T | RNA (SNP) | VAF 37/190 reads (19%) | catalogued as rs765683104; called by muse, mutect2, varscan2
- SLIT2 | c.179+1052C>A | Intron (SNP) | VAF 120/306 reads (39%) | called by muse, mutect2, varscan2
- TAZ | c.*173A>T | 3'UTR (SNP) | VAF 310/329 reads (94%) | called by muse, mutect2, varscan2
- TMEM116 | c.-118T>G | 5'UTR (SNP) | VAF 54/226 reads (24%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071155 C>T | 3'Flank (SNP) | VAF 145/279 reads (52%) | called by muse, mutect2, varscan2
- ZBP1 | c.*152G>A | 3'UTR (SNP) | VAF 97/223 reads (43%) | called by muse, mutect2, varscan2
- ZNF44 | c.*154A>T | 3'UTR (SNP) | VAF 70/144 reads (49%) | called by muse, mutect2, varscan2
